Somatic mutation profile of tumor specimen C3N-06995-01 (aliquot CPT0465830006) from CPTAC case C3N-06995, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 74.6 years (27,264 days).
Specimen C3N-06995-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 771d164c-d364-4c7f-9711-bf8068b1d18e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06995-31 (Blood Derived Normal), aliquot CPT0465920005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5621289-8e3f-4d74-a75e-5d496d511dce

The open-access MAF lists 773 somatic variants for this specimen: 493 protein-altering or splice-affecting, 249 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 443, Silent 249, Nonsense Mutation 30, Intron 17, Splice Site 7, 5'Flank 5, Splice Region 5, 3'UTR 4, Frame Shift Del 4, 3'Flank 3, Nonstop Mutation 2, RNA 2.

Variants (750 of 773; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1876G>A p.E626K (on ENST00000288602 / NM_001374244.1; = p.E586K on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs121913340, COSV56082407, COSV56115488; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CAV3 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs116840778, CM003420; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 211/492 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN3A | c.3998C>T p.P1333L | Missense Mutation (SNP) | VAF 79/384 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs1026841366, COSV50967889; called by muse, mutect2, varscan2
- ABCA7 | c.351T>G p.S117R | Missense Mutation (SNP) | VAF 135/471 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746400634; called by muse, mutect2, varscan2
- ABCC1 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as COSV100578892; called by muse, mutect2, varscan2
- ACSM2A | c.1073G>A p.R358Q (on ENST00000219054; = p.R279Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs188648395, COSV54581766, COSV99525176; called by muse, mutect2, varscan2
- ACTRT1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 155/484 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV64419728; called by muse, mutect2, varscan2
- ADAM32 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 105/579 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as COSV65948337; called by muse, mutect2, varscan2
- ADAMTS19 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs1363507177; called by muse, mutect2, varscan2
- ADGRF4 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs765746255, COSV51954586; called by muse, mutect2, varscan2
- ADGRV1 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67979912; called by muse, mutect2, varscan2
- ADGRV1 | c.12146C>T p.S4049F | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.223); catalogued as COSV67981721; called by muse, mutect2, varscan2
- ADH6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756863693, COSV52955529; called by muse, mutect2, varscan2
- AHNAK2 | c.7654C>T p.P2552S | Missense Mutation (SNP) | VAF 332/751 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs532347726, COSV100315193; called by muse, mutect2, varscan2
- AKNAD1 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 100/368 reads (27%) | catalogued as COSV62199265; called by muse, mutect2, varscan2
- AL358113.1 | c.3353C>T p.P1118L | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1288468467; called by muse, mutect2, varscan2
- AMER1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 130/557 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV57657065; called by muse, mutect2, varscan2
- ANK3 | c.7966G>A p.G2656R | Missense Mutation (SNP) | VAF 97/444 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs760624949, COSV55065148, COSV99780769; called by muse, mutect2, varscan2
- ANKRD26 | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 80/318 reads (25%) | catalogued as rs776024539, COSV65779262; called by muse, mutect2, varscan2
- ANXA8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 98/873 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1234169612; called by muse, mutect2, varscan2
- AOX1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs150771380; called by muse, mutect2, varscan2
- AP2M1 | c.1305_*9del | Nonstop Mutation (DEL) | VAF 48/206 reads (23%) | catalogued as rs776432860; called by mutect2, pindel, varscan2
- ARHGAP29 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV53110737; called by muse, mutect2, varscan2
- ARHGEF12 | c.3529C>T p.P1177S | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.541); catalogued as rs1209704438; called by muse, mutect2, varscan2
- ASAH2 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 83/369 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV61483223; called by muse, mutect2, varscan2
- ASPSCR1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 229/692 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs760536415; called by muse, mutect2, varscan2
- ATF5 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1344693052; called by muse, mutect2, varscan2
- ATP10B | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1439840167, COSV58778473; called by muse, mutect2, varscan2
- B3GAT1 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 69/388 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs1298498591, COSV57001084; called by muse, mutect2, varscan2
- BCL11A | c.1292C>T p.S431F (on ENST00000335712 / NM_001365609.1; = p.S465F on NM_018014.4) | Missense Mutation (SNP) | VAF 121/545 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV59635284; called by muse, mutect2, varscan2
- BEST3 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs756698970, COSV58305708; called by muse, mutect2, varscan2
- BIRC6 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.06); catalogued as rs1345802454; called by muse, mutect2, varscan2
- BRINP2 | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 333/553 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1205221972; called by muse, mutect2, varscan2
- BRPF3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 225/576 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV60208444; called by muse, mutect2, varscan2
- BUB1B | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 80/346 reads (23%) | catalogued as rs200884355, COSV99807071; called by muse, mutect2, varscan2
- C6 | c.1704G>A p.W568* | Nonsense Mutation (SNP) | VAF 55/227 reads (24%) | catalogued as rs1163983831; called by muse, mutect2, varscan2
- CACNA1H | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs771952308; called by muse, mutect2, varscan2
- CAMK1D | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs148446769; called by muse, mutect2, varscan2
- CDX4 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868321760, COSV65171686; called by muse, mutect2, varscan2
- CFAP47 | c.4808G>A p.G1603E | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57972318; called by muse, mutect2, varscan2
- CFAP54 | c.3757G>A p.E1253K | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1237682893, COSV101598512, COSV73047070; called by muse, mutect2, varscan2
- CLEC4D | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs946297864, COSV55230883; called by muse, mutect2, varscan2
- CMYA5 | c.10370C>T p.S3457F | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV71405563; called by muse, mutect2, varscan2
- CNBD2 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs754558131; called by muse, mutect2, varscan2
- COL11A2 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 159/595 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV59502543; called by muse, mutect2, varscan2
- COL6A2 | c.2992C>T p.H998Y | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1343015254; called by muse, mutect2, varscan2
- CRIM1 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 95/383 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.467); catalogued as rs761241012, COSV99754181; called by muse, mutect2, varscan2
- CSGALNACT1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 108/608 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs762817210; called by muse, mutect2, varscan2
- CSMD2 | c.4882G>A p.G1628R | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174433363, COSV53913344; called by muse, mutect2, varscan2
- CSMD3 | c.3151G>A p.E1051K (on ENST00000297405 / NM_001363185.1; = p.E947K on NM_052900.3) | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); catalogued as rs764801003, COSV52140582; called by muse, mutect2, varscan2
- CTNNA2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV63554933; called by muse, mutect2, varscan2
- CTNNA2 | c.2395G>T p.V799L | Missense Mutation (SNP) | VAF 75/335 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58137694; called by muse, mutect2, varscan2
- CTNND2 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 115/473 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as rs759309910, COSV58922112; called by muse, mutect2, varscan2
- CTNND2 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV58889458; called by muse, mutect2, varscan2
- CUBN | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 86/376 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV64711125; called by muse, mutect2, varscan2
- DDX31 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 154/415 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs867691694; called by muse, mutect2, varscan2
- DDX42 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 134/347 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.617); catalogued as COSV63790044; called by muse, mutect2, varscan2
- DENND3 | c.3440G>A p.G1147E | Missense Mutation (SNP) | VAF 113/589 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52807471; called by muse, mutect2, varscan2
- DLGAP2 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 283/749 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.148); catalogued as rs780394886; called by muse, mutect2, varscan2
- DNAAF5 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 107/623 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.227); catalogued as rs987496902; called by muse, mutect2, varscan2
- DNAH2 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs1486437654; called by muse, mutect2, varscan2
- DPAGT1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776632995, CM126444, COSV53829477; called by muse, mutect2, varscan2
- DPF2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52888034; called by muse, mutect2, varscan2
- DSP | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101131722; called by muse, mutect2, varscan2
- DZIP1 | c.2411G>A p.G804E (on ENST00000347108; = p.G785E on NM_014934.5) | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs1016281699, COSV61265333; called by muse, mutect2, varscan2
- EFCAB12 | c.1405-1G>A p.X469_splice (on ENST00000326085; = p.K468= on NM_207307.3) | Splice Site (SNP) | VAF 87/313 reads (28%) | catalogued as COSV100394878; called by muse, mutect2, varscan2
- EGFLAM | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.042); catalogued as COSV59295169; called by muse, mutect2, varscan2
- EPG5 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 111/389 reads (29%) | catalogued as rs745425455, COSV99956259; called by muse, mutect2, varscan2
- ETV1 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 155/432 reads (36%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.928); catalogued as COSV54151697; called by muse, mutect2, varscan2
- FAM184A | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs865833457, COSV58854479; called by muse, mutect2, varscan2
- FAM47C | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 139/533 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63731112; called by muse, mutect2, varscan2
- FAM83B | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 84/291 reads (29%) | catalogued as rs367914924; called by muse, mutect2, varscan2
- FAT3 | c.5623G>A p.D1875N | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.325); catalogued as COSV53127603; called by muse, mutect2, varscan2
- FAT3 | c.9599C>T p.S3200L | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.476); catalogued as rs376790690; called by muse, mutect2, varscan2
- FBN3 | c.5845G>A p.E1949K | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1328150230, COSV54464780; called by muse, mutect2, varscan2
- FN1 | c.4228C>T p.R1410W | Missense Mutation (SNP) | VAF 93/443 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868144707, COSV60551017; called by muse, mutect2, varscan2
- FN1 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs201863538, COSV100118473, COSV60566745; called by muse, mutect2, varscan2
- FREM2 | c.8498A>G p.N2833S | Missense Mutation (SNP) | VAF 83/345 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV54837227; called by muse, mutect2, varscan2
- FUBP1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1448114956; called by muse, mutect2, varscan2
- FYB2 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58588801; called by muse, mutect2, varscan2
- GALNT8 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52899378; called by muse, mutect2, varscan2
- GC | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs372964536, COSV99910060; called by muse, mutect2, varscan2
- GJA4 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 108/513 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs757783086; called by muse, mutect2, varscan2
- GJC3 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 309/637 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57209963; called by muse, mutect2, varscan2
- GPATCH1 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50118308; called by muse, mutect2, varscan2
- GPR142 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 197/482 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59520712; called by muse, mutect2, varscan2
- GRB14 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598952, COSV55736590; called by muse, mutect2, varscan2
- GRM3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 84/727 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473539; called by muse, mutect2, varscan2
- GRM6 | c.2136G>A p.M712I | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs754893934; called by muse, mutect2, varscan2
- HCAR2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 100/616 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs200721962, COSV61025849; called by muse, mutect2, varscan2
- HEATR5B | c.3805C>T p.H1269Y | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359600541; called by muse, mutect2, varscan2
- HELZ2 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 116/493 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs1190597114, COSV64409676; called by muse, mutect2, varscan2
- HRNR | c.2881G>A p.G961S | Missense Mutation (SNP) | VAF 409/678 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as rs1303172060, COSV100913817; called by muse, mutect2, varscan2
- HTR2C | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 170/603 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1556487133, COSV52208053; called by muse, varscan2
- IDS | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 98/429 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1557340600; called by muse, mutect2, varscan2
- IGLL5 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 181/718 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); catalogued as rs375027597; called by muse, mutect2, varscan2
- ILDR1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56548770; called by muse, mutect2, varscan2
- INPP5D | c.3380C>T p.S1127L (on ENST00000445964 / NM_001017915.3; = p.S1126L on NM_005541.5) | Missense Mutation (SNP) | VAF 116/468 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs534965684, COSV64036625; called by muse, mutect2, varscan2
- ISM2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 165/407 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs1403849380; called by muse, mutect2, varscan2
- ITIH1 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 101/400 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776980256; called by muse, mutect2, varscan2
- KCNC2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV54378296; called by muse, mutect2, varscan2
- KCNH5 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59770208; called by muse, mutect2, varscan2
- KCNT2 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 238/406 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV54101026; called by muse, mutect2, varscan2
- KCNU1 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 85/493 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV67754437; called by muse, mutect2, varscan2
- KIF26B | c.4799C>T p.P1600L | Missense Mutation (SNP) | VAF 504/801 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1349961054; called by muse, mutect2, varscan2
- KLHL13 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV100900203; called by muse, mutect2, varscan2
- KLHL15 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 140/556 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); catalogued as COSV60142173; called by muse, mutect2, varscan2
- KRT1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 71/332 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99358431; called by muse, mutect2, varscan2
- KRT23 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 105/476 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52928205; called by muse, mutect2, varscan2
- LIPN | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs981221050, COSV68384142; called by muse, mutect2, varscan2
- LPA | c.3947G>A p.G1316D | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV60301108, COSV60305398; called by muse, mutect2, varscan2
- LRRD1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 125/325 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396067766; called by muse, mutect2, varscan2
- LUM | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs754865952, COSV57127574; called by muse, mutect2, varscan2
- MAGEB6 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 106/487 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs868530714, COSV66872666; called by muse, mutect2, varscan2
- MAGED1 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 136/531 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.369); catalogued as rs782279092, COSV58516654; called by muse, mutect2, varscan2
- MARCO | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs781687384, COSV59057551; called by muse, mutect2, varscan2
- MGAM | c.4069G>A p.D1357N | Missense Mutation (SNP) | VAF 109/590 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101527717, COSV72075207; called by muse, mutect2, varscan2
- MKRN2OS | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 98/429 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs867884079; called by muse, mutect2, varscan2
- MORC1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs138435095, COSV51713000; called by muse, mutect2, varscan2
- MORC3 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV68203633; called by muse, mutect2, varscan2
- MPP4 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs1559015045; called by muse, mutect2, varscan2
- MUC12 | c.12602C>T p.S4201L (on ENST00000379442; = p.S4058L on NM_001164462.1) | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0); catalogued as rs1396000833; called by muse, mutect2
- MUC16 | c.14821C>T p.P4941S | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.112); catalogued as rs765374250, COSV67443915, COSV67492554; called by muse, mutect2, varscan2
- MUC17 | c.6125G>A p.R2042Q | Missense Mutation (SNP) | VAF 83/525 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs373744994, COSV100075493; called by muse, mutect2, varscan2
- MUC22 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 151/570 reads (26%) | SIFT tolerated (0.49); catalogued as rs1317042076; called by muse, mutect2, varscan2
- MUC7 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 126/520 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.348); catalogued as COSV59217537; called by muse, mutect2, varscan2
- MUS81 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 138/517 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1211525012; called by muse, mutect2, varscan2
- MXRA5 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 131/577 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV54243531; called by muse, mutect2, varscan2
- MYH13 | c.645+1G>A p.X215_splice | Splice Site (SNP) | VAF 41/160 reads (26%) | catalogued as rs753387344; called by muse, mutect2, varscan2
- MYH8 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV67959790; called by muse, mutect2, varscan2
- NAT10 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs1253347709, COSV57664546; called by muse, mutect2, varscan2
- NBEA | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868169550, COSV59765311; called by muse, mutect2, varscan2
- NCOA7 | c.2611C>T p.H871Y | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs769627087; called by muse, mutect2, varscan2
- NF2 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs765540111, CM942127, COSV58520023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 101/461 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, mutect2, varscan2
- NIPA2 | c.920C>G p.A307G | Missense Mutation (SNP) | VAF 116/466 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as rs143997361; called by muse, mutect2, varscan2
- NLRP13 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61623642; called by muse, mutect2, varscan2
- NLRP5 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs866667224, COSV101173480; called by muse, mutect2, varscan2
- NLRP8 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.274); catalogued as rs761831926, COSV52583592, COSV52587481; called by muse, mutect2, varscan2
- NOS2 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs377596177; called by muse, mutect2, varscan2
- NOTCH3 | c.4471G>A p.E1491K | Missense Mutation (SNP) | VAF 151/550 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.51); catalogued as rs1427054593; called by muse, mutect2, varscan2
- NPHP4 | c.2891C>T p.A964V | Missense Mutation (SNP) | VAF 114/443 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV65398040; called by muse, mutect2, varscan2
- NPIPB15 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 146/936 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1375561111; called by muse, mutect2
- NT5DC2 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs868553212; called by muse, mutect2, varscan2
- OLFM4 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 118/436 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141840932, COSV54575803; called by muse, mutect2, varscan2
- OR4F6 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1052237426, COSV104410388; called by muse, mutect2, varscan2
- OR6C4 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 66/299 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV67793053; called by muse, mutect2, varscan2
- OR6S1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 122/481 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs747116853, COSV57839013; called by muse, mutect2, varscan2
- P2RY8 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 133/521 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.039); catalogued as COSV67177355; called by muse, mutect2, varscan2
- PAPPA | c.3703G>A p.G1235S | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs139845956, COSV100074014; called by muse, mutect2, varscan2
- PASD1 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1434722032; called by muse, mutect2, varscan2
- PCDHB4 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 102/429 reads (24%) | catalogued as rs375620247; called by muse, mutect2, varscan2
- PDE9A | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs146611085, COSV52323986; called by muse, mutect2, varscan2
- PDZK1IP1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.16); catalogued as rs768148219; called by muse, mutect2, varscan2
- PDZK1IP1 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 98/404 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs763420662; called by muse, mutect2, varscan2
- PER1 | c.1961C>T p.S654F | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs372999068; called by muse, mutect2, varscan2
- PHACTR3 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 135/525 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203567782, COSV63027567; called by muse, mutect2, varscan2
- PIK3C2G | c.3511G>A p.G1171R (on ENST00000676171; = p.G1130R on NM_004570.5) | Missense Mutation (SNP) | VAF 89/342 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1370164516, COSV99853561; called by muse, mutect2, varscan2
- PKHD1L1 | c.9961G>T p.V3321L | Missense Mutation (SNP) | VAF 144/339 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV65744275; called by muse, mutect2, varscan2
- PLA2G12B | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs780706700; called by muse, mutect2, varscan2
- PLPPR3 | c.1324G>A p.E442K (on ENST00000520876 / NM_001270366.2; = p.E470K on NM_024888.2) | Missense Mutation (SNP) | VAF 113/582 reads (19%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.468); catalogued as rs1280664376; called by muse, mutect2, varscan2
- POR | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 106/602 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1554558814; called by muse, mutect2, varscan2
- PPFIA2 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866768312; called by muse, mutect2, varscan2
- PPIP5K2 | c.3040C>T p.P1014S | Missense Mutation (SNP) | VAF 132/389 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.778); catalogued as COSV100383721; called by muse, mutect2, varscan2
- PPM1E | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 159/412 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs755292115, COSV57570226, COSV57575623; called by muse, mutect2, varscan2
- PPP1R3A | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 84/470 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777816791, COSV52876449, COSV52879504, COSV52879604; called by muse, mutect2, varscan2
- PPT2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 104/391 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs752330755; called by muse, mutect2, varscan2
- PRR14L | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 93/390 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57888292; called by muse, mutect2, varscan2
- PRR36 | c.3911G>C p.R1304P | Missense Mutation (SNP) | VAF 147/527 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54486048; called by muse, mutect2, varscan2
- PRRC2A | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 101/438 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV63224525; called by muse, mutect2, varscan2
- PRSS37 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 106/632 reads (17%) | catalogued as rs1489362668, COSV63339313, COSV63339647; called by muse, mutect2, varscan2
- RASGRP2 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 119/498 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62448991; called by muse, mutect2, varscan2
- RASGRP4 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 117/521 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs760304432; called by muse, mutect2, varscan2
- RASGRP4 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 117/526 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV53039839; called by muse, mutect2, varscan2
- RASIP1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 133/510 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV55805409; called by muse, mutect2, varscan2
- RBM47 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55935214; called by muse, mutect2, varscan2
- RFPL3 | c.934C>T p.R312C (on ENST00000249007 / NM_001098535.1; = p.R283C on NM_006604.2) | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.224); catalogued as rs369320148; called by muse, mutect2, varscan2
- RIMS2 | c.1441G>A p.D481N (on ENST00000666250 / NM_001348490.2; = p.D289N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 213/554 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99173196; called by muse, mutect2, varscan2
- RNGTT | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 75/331 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763371848, COSV55646778; called by muse, mutect2, varscan2
- RSPH14 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as rs1292954187; called by muse, mutect2, varscan2
- RUNDC3B | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1235770568, COSV56694702; called by muse, mutect2, varscan2
- SEL1L2 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs373099694; called by muse, mutect2, varscan2
- SETBP1 | c.3695C>T p.S1232F | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56333220; called by muse, mutect2, varscan2
- SEZ6 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 124/487 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100253287; called by muse, mutect2, varscan2
- SLC22A10 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs374740617, COSV100235794; called by muse, mutect2, varscan2
- SLC4A1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV52258661; called by muse, mutect2, varscan2
- SLC8A3 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 176/492 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs953918295, COSV63521014; called by muse, mutect2, varscan2
- SLC9A2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs867313703, COSV52131432, COSV99295912; called by muse, mutect2, varscan2
- SLC9A9 | c.1880G>A p.G627D | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs777776846, COSV57227336; called by muse, mutect2, varscan2
- SLCO4C1 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 87/356 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs766119306; called by muse, mutect2, varscan2
- SLCO6A1 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 89/381 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV65806173; called by muse, mutect2, varscan2
- SLITRK4 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 98/393 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100567232, COSV62022929; called by muse, mutect2, varscan2
- SMR3A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/314 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56951266; called by muse, varscan2
- SNAP91 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 97/397 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs780980872; called by muse, mutect2, varscan2
- SORBS1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV53358938; called by muse, mutect2, varscan2
- SPANXN3 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 112/414 reads (27%) | catalogued as COSV100980868; called by muse, mutect2, varscan2
- SPHKAP | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60875038; called by muse, mutect2, varscan2
- SPZ1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 99/396 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs199787885, COSV57062860; called by muse, mutect2, varscan2
- SRCAP | c.7112C>T p.S2371F | Missense Mutation (SNP) | VAF 125/514 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs540911812, COSV52674942; called by muse, mutect2, varscan2
- STARD13 | c.986C>T p.S329L (on ENST00000336934 / NM_001243476.3; = p.S211L on NM_052851.3) | Missense Mutation (SNP) | VAF 116/457 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs1174248196; called by muse, mutect2, varscan2
- TAS2R39 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 99/634 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV71471019; called by muse, mutect2, varscan2
- TBC1D17 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as rs771946065; called by muse, mutect2, varscan2
- TBX6 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 78/356 reads (22%) | catalogued as rs994246265; called by muse, mutect2, varscan2
- TEX35 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 213/337 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs200491990, COSV51103784; called by muse, mutect2, varscan2
- THAP4 | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 126/477 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100398348; called by muse, mutect2, varscan2
- THRB | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 106/415 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867926730, COSV54979328; called by muse, mutect2, varscan2
- THSD7B | c.3340G>A p.E1114K (on ENST00000272643; = p.E1112K on NM_001316349.2) | Missense Mutation (SNP) | VAF 129/488 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV55652012; called by muse, mutect2, varscan2
- TLL2 | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 92/338 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772160239, COSV63571463; called by muse, mutect2, varscan2
- TMPRSS11F | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs137965399; called by muse, mutect2, varscan2
- TMPRSS7 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 85/349 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs1404517189; called by muse, mutect2, varscan2
- TPTE | c.686G>A p.R229Q (on ENST00000618007 / NM_199261.4; = p.R211Q on NM_199259.4) | Missense Mutation (SNP) | VAF 65/617 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs566493792; called by muse, mutect2, varscan2
- TRAV8-3 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 111/438 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.43); catalogued as rs868476190; called by muse, mutect2, varscan2
- TRIML2 | c.1200C>A p.F400L | Missense Mutation (SNP) | VAF 122/495 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV104399977, COSV58716213; called by muse, mutect2, varscan2
- TTC6 | c.145G>T p.G49* (on ENST00000267368; = p.G1318* on NM_001310135.3) | Nonsense Mutation (SNP) | VAF 106/365 reads (29%) | catalogued as COSV57447127; called by muse, mutect2, varscan2
- TUBB8 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59115796; called by muse, mutect2, varscan2
- TULP2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 89/384 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV55479719; called by muse, mutect2, varscan2
- UBXN2A | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455513231; called by muse, mutect2, varscan2
- UGT2B15 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs781349863; called by muse, mutect2, varscan2
- UGT3A2 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV56928272, COSV56930932; called by muse, mutect2, varscan2
- VEGFD | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 121/465 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV99938297; called by muse, mutect2, varscan2
- VGLL3 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 120/464 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67354038; called by muse, varscan2
- WDR87 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV58200464; called by muse, mutect2, varscan2
- WNT3 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 170/751 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.975); catalogued as COSV56646346, COSV99842966; called by muse, mutect2, varscan2
- WNT8B | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs556948230, COSV59324358; called by muse, mutect2, varscan2
- ZFYVE28 | c.2430C>T p.D810= | Splice Region (SNP) | VAF 75/338 reads (22%) | catalogued as rs1025736040, COSV99343222; called by muse, mutect2, varscan2
- ZHX2 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 99/527 reads (19%) | catalogued as rs778504466; called by muse, mutect2, varscan2
- ZNF175 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV51798483; called by muse, mutect2, varscan2
- ZNF180 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 108/454 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV55421315; called by muse, mutect2, varscan2
- ZNF235 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.543); catalogued as COSV52156503; called by muse, mutect2, varscan2
- ZNF251 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 277/723 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs375520552; called by muse, mutect2, varscan2
- ZNF276 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs377060397; called by muse, mutect2, varscan2
- ZNF728 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs775730586; called by muse, mutect2, varscan2
- ZNF729 | c.2704C>T p.H902Y | Missense Mutation (SNP) | VAF 112/462 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62601930, COSV62606989; called by muse, mutect2
- ZNF835 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 98/376 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as rs1422731054, COSV101606380; called by muse, mutect2, varscan2
- ZSCAN23 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 142/453 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57044056; called by muse, mutect2, varscan2
- AADACL4 | c.272A>C p.D91A | Missense Mutation (SNP) | VAF 94/436 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- AASS | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 195/409 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ABCA9 | c.4825G>A p.D1609N | Missense Mutation (SNP) | VAF 151/414 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCD4 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 108/539 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- AC007040.2 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AC119396.1 | c.786-1G>A p.X262_splice | Splice Site (SNP) | VAF 79/365 reads (22%) | called by muse, mutect2, varscan2
- ACOXL | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ACSM2A | c.1100G>A p.G367E (on ENST00000219054; = p.G288E on NM_001308169.2) | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ACSM3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 109/409 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ACSM3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 108/406 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTS16 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.14587T>A p.Y4863N | Missense Mutation (SNP) | VAF 144/490 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ALCAM | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ALPG | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 178/660 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2
- ALPK2 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 123/462 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKS1B | c.3323C>T p.S1108F (on ENST00000547776 / NM_152788.4; = p.S274F on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP3S1 | c.289T>A p.L97I | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- APOB | c.8444C>T p.S2815L | Missense Mutation (SNP) | VAF 107/408 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF12 | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ASXL3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ATF7IP | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ATXN7L1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 92/444 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- AUTS2 | c.3310C>T p.L1104F | Missense Mutation (SNP) | VAF 358/724 reads (49%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- AXIN2 | c.2440T>C p.C814R | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AXIN2 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 196/503 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BCAS2 | c.677G>T p.*226Lext*36 | Nonstop Mutation (SNP) | VAF 55/283 reads (19%) | called by muse, mutect2, varscan2
- BCL6 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 131/553 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- BCOR | c.4339C>T p.R1447C (on ENST00000378444 / NM_001123385.2; = p.R1413C on NM_017745.6) | Missense Mutation (SNP) | VAF 150/601 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BMPR1B | c.1107C>A p.N369K | Missense Mutation (SNP) | VAF 96/354 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- C12orf29 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C1R | c.1393T>A p.C465S (on ENST00000536053 / NM_001354346.2; = p.C451S on NM_001733.7) | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- C3 | c.4135G>A p.D1379N | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- C4orf50 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- C7orf26 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 133/611 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CABP5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.6557C>T p.A2186V (on ENST00000367573 / NM_001205293.3; = p.A2143V on NM_000721.4) | Missense Mutation (SNP) | VAF 344/565 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CACNB2 | c.1303-1G>A p.X435_splice (on ENST00000324631 / NM_201596.3; = p.X380_splice on NM_000724.4) | Splice Site (SNP) | VAF 58/250 reads (23%) | called by muse, mutect2, varscan2
- CCBE1 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCL15 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 82/431 reads (19%) | called by muse, varscan2
- CDK12 | c.3808C>T p.P1270S (on ENST00000447079 / NM_016507.4; = p.P1261S on NM_015083.3) | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- CDS1 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CENPP | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CFAP46 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 100/437 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CFH | c.3623C>T p.S1208L | Missense Mutation (SNP) | VAF 320/534 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CHRNA9 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 105/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIR1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CLCNKB | c.2030T>A p.I677N | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CLEC6A | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 78/276 reads (28%) | called by muse, mutect2, varscan2
- COL14A1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL22A1 | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 107/503 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A5 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- COL9A2 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 111/415 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- COX10 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 89/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CRTC1 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 89/389 reads (23%) | called by muse, mutect2, varscan2
- CRYBG3 | c.6778C>T p.Q2260* | Nonsense Mutation (SNP) | VAF 99/348 reads (28%) | called by muse, mutect2, varscan2
- CSMD1 | c.1751C>T p.S584L (on ENST00000520002; = p.S583L on NM_033225.6) | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, varscan2
- CTNNA2 | c.2396T>G p.V799G | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTR9 | c.1194G>A p.K398= | Splice Region (SNP) | VAF 57/250 reads (23%) | called by muse, mutect2, varscan2
- CTR9 | c.2569del p.E859Nfs*146 | Frame Shift Del (DEL) | VAF 76/294 reads (26%) | called by mutect2, pindel, varscan2
- CX3CR1 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 124/436 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2A13 | c.739T>A p.F247I | Missense Mutation (SNP) | VAF 123/555 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CYRIA | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 77/395 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDX60 | c.4958G>A p.G1653E | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DDX60 | c.4427C>T p.S1476F | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- DDX60L | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 92/433 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DGKK | c.2315C>T p.S772F | Missense Mutation (SNP) | VAF 110/463 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLD | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 178/318 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DMGDH | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, varscan2
- DMXL2 | c.2585A>C p.K862T | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DNAH1 | c.9520G>C p.D3174H | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DNAH7 | c.9010A>T p.M3004L | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- EIF2A | c.382dup p.M128Nfs*12 | Frame Shift Ins (INS) | VAF 57/235 reads (24%) | called by mutect2, varscan2
- EIF3A | c.212del p.L71Yfs*11 | Frame Shift Del (DEL) | VAF 71/333 reads (21%) | called by mutect2, pindel, varscan2
- EMID1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 104/457 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EOMES | c.1380-5C>T | Splice Region (SNP) | VAF 93/380 reads (24%) | called by muse, mutect2, varscan2
- ERN2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 98/403 reads (24%) | called by muse, mutect2, varscan2
- EVPL | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 152/461 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, varscan2
- EYA2 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM47A | c.1627C>G p.L543V | Missense Mutation (SNP) | VAF 179/634 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- FAM47A | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 130/538 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FANCB | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 98/425 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- FREM2 | c.1412G>A p.S471N | Missense Mutation (SNP) | VAF 108/445 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FRMPD3 | c.2232C>A p.D744E | Missense Mutation (SNP) | VAF 109/517 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GABRA1 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GATA1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 156/688 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- GCA | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 85/405 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GFRA1 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- GIMD1 | c.352T>A p.F118I | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- GLI2 | c.1486G>A p.A496T (on ENST00000361492 / NM_001374353.1; = p.A513T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GMPS | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GPC5 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GPR160 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 82/297 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- GPR37L1 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 320/524 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR61 | c.899G>A p.W300* | Nonsense Mutation (SNP) | VAF 144/557 reads (26%) | called by muse, mutect2, varscan2
- GSTA2 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, varscan2
- H3C3 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 82/381 reads (22%) | called by muse, mutect2, varscan2
- HCFC1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 134/489 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.048); called by muse, varscan2
- HELZ2 | c.6303C>T p.L2101= (on ENST00000467148 / NM_001037335.2; = p.L1532= on NM_033405.3) | Splice Region (SNP) | VAF 65/273 reads (24%) | called by muse, mutect2, varscan2
- HHLA2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPS3 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HSPA12A | c.1004T>G p.L335R | Missense Mutation (SNP) | VAF 81/339 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- IGHM | c.1419G>A p.V473= | Splice Region (SNP) | VAF 89/487 reads (18%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 105/376 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- INPP5J | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 112/479 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQANK1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 95/460 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IQCA1L | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 218/441 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IQCA1L | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 73/559 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ITGA8 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA9 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ITPR1 | c.3643G>A p.V1215M (on ENST00000354582; = p.V1200M on NM_002222.7) | Missense Mutation (SNP) | VAF 99/368 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ITPRID2 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KALRN | c.4713G>A p.W1571* | Nonsense Mutation (SNP) | VAF 74/303 reads (24%) | called by muse, mutect2, varscan2
- KCNJ11 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 106/410 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KDM4D | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIAA1217 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 110/437 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KIF26B | c.4002G>T p.K1334N | Missense Mutation (SNP) | VAF 436/726 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- KL | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 120/453 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- KLKB1 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KMT2B | c.5719C>T p.P1907S | Missense Mutation (SNP) | VAF 137/533 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KNG1 | c.1187T>C p.I396T | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP4-9 | c.376C>A p.R126S | Missense Mutation (SNP) | VAF 148/664 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, varscan2
- LDLRAD2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 143/553 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LMF2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 126/473 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMOD1 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 108/601 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LRP2 | c.7331G>A p.G2444E | Missense Mutation (SNP) | VAF 105/411 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- LRP2 | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC17 | c.619A>T p.K207* | Nonsense Mutation (SNP) | VAF 82/502 reads (16%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.65G>A p.W22* | Nonsense Mutation (SNP) | VAF 127/1559 reads (8%) | called by muse, mutect2
- LRRC4B | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 130/515 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- MAB21L4 | c.1048G>A p.G350S (on ENST00000388934 / NM_001085437.3; = p.G182S on NM_024861.4) | Missense Mutation (SNP) | VAF 139/536 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- MAGEB6B | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MAGI1 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 103/445 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MARCO | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 110/468 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MASP2 | c.1249T>A p.F417I | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MEIS2 | c.250C>T p.P84S (on ENST00000561208 / NM_170675.5; = p.P71S on NM_002399.3) | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MINDY4B | c.897+1G>A p.X299_splice | Splice Site (SNP) | VAF 75/327 reads (23%) | called by muse, mutect2, varscan2
- MIS12 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 100/377 reads (27%) | called by muse, mutect2, varscan2
- MLPH | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 113/424 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC16 | c.23566C>T p.P7856S | Missense Mutation (SNP) | VAF 79/404 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.21713A>T p.K7238I | Missense Mutation (SNP) | VAF 110/406 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MUC5B | c.11200C>T p.P3734S | Missense Mutation (SNP) | VAF 84/505 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MX2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 102/426 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.5962G>A p.D1988N | Missense Mutation (SNP) | VAF 154/587 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MYH15 | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MYH6 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 89/355 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MYOF | c.5198G>A p.R1733K | Missense Mutation (SNP) | VAF 115/463 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NBAS | c.6760C>T p.P2254S | Missense Mutation (SNP) | VAF 97/416 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- NBAS | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- NCAN | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 127/493 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NCOR2 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by mutect2, varscan2
- NEURL1B | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 98/376 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NEXMIF | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 168/644 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- NHSL2 | c.1082C>T p.S361F (on ENST00000510661; = p.S727F on NM_001013627.2) | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NME9 | c.610C>T p.L204F (on ENST00000333911 / NM_001349024.2; = p.L143F on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- NMRK2 | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 65/331 reads (20%) | called by muse, mutect2, varscan2
- NR1I2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 114/489 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NSUN7 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NUGGC | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 112/501 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NXPE2 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- OR10A6 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 103/441 reads (23%) | called by muse, mutect2, varscan2
- OR13H1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 136/462 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR1L3 | c.503T>A p.F168Y | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2H2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 151/627 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- OR3A3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR56A5 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6V1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 384/824 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- OTOG | c.2890C>T p.P964S | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OXR1 | c.867T>A p.D289E (on ENST00000442977 / NM_001198532.1; = p.D288E on NM_018002.3) | Missense Mutation (SNP) | VAF 95/258 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPSS2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHB5 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 201/758 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PCSK1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDIA4 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 88/557 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PIEZO2 | c.8229G>A p.M2743I | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PIK3C2A | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PLA2R1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCXD1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 108/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PLRG1 | c.1512G>A p.W504* | Nonsense Mutation (SNP) | VAF 55/255 reads (22%) | called by muse, mutect2, varscan2
- POTEA | c.1016G>A p.R339K (on ENST00000519951 / NM_001005365.2; = p.R293K on NM_001002920.1) | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PPP6R3 | c.587_606del p.V196Afs*15 | Frame Shift Del (DEL) | VAF 25/299 reads (8%) | called by mutect2, pindel
- PRAMEF18 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 69/692 reads (10%) | called by muse, mutect2, varscan2
- PRAMEF8 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 103/467 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PRRC2A | c.5656G>A p.A1886T | Missense Mutation (SNP) | VAF 115/609 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PTCHD3 | c.1063A>C p.N355H | Missense Mutation (SNP) | VAF 114/425 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPN6 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRQ | c.5873C>T p.S1958L (on ENST00000616559; = p.S1916L on NM_001145026.2) | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PYCR1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 230/642 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- PYGM | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RADIL | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 104/736 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.416); called by muse, mutect2
- RBM14 | c.1803-1G>A p.X601_splice | Splice Site (SNP) | VAF 76/245 reads (31%) | called by muse, mutect2, varscan2
- RBP3 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 114/488 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- RHBDF2 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- RHOV | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMBP2 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 129/490 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- RIPPLY1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ROS1 | c.5306T>G p.I1769R | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- RP1 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 131/336 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RPL13 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- RYR1 | c.3473C>T p.T1158I | Missense Mutation (SNP) | VAF 81/350 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RYR3 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- RYR3 | c.7144C>T p.H2382Y (on ENST00000389232; = p.H2383Y on NM_001036.6) | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- S100A14 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 202/336 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- SAXO1 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SBNO2 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 134/493 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SERPINB3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SFXN5 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SIGLEC14 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIGLEC5 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO1C1 | c.1235T>A p.I412K | Missense Mutation (SNP) | VAF 86/377 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- SLCO2B1 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 87/340 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLFN14 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIRP | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 165/407 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLIT3 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMAP1 | c.713C>T p.P238L (on ENST00000370455 / NM_001044305.3; = p.P211L on NM_021940.5) | Missense Mutation (SNP) | VAF 90/397 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMC1B | c.2867G>A p.G956E | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SOBP | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 129/415 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SOX18 | c.825del p.A276Rfs*90 | Frame Shift Del (DEL) | VAF 48/306 reads (16%) | called by pindel, varscan2
- SPTBN5 | c.7976C>T p.A2659V | Missense Mutation (SNP) | VAF 84/407 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SRCAP | c.7735C>T p.L2579F | Missense Mutation (SNP) | VAF 127/516 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SRGAP2 | c.1354-1G>A p.X452_splice (on ENST00000624873 / NM_001170637.4; = p.X453_splice on NM_015326.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 146/245 reads (60%) | called by muse, mutect2, varscan2
- SUN1 | c.1822C>G p.Q608E (on ENST00000405266 / NM_001367651.1; = p.Q488E on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 204/543 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNRG | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 104/431 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAF3 | c.2045T>C p.L682S | Missense Mutation (SNP) | VAF 91/393 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD9 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TENM1 | c.5360G>A p.R1787K | Missense Mutation (SNP) | VAF 78/378 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TESMIN | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); called by muse, varscan2
- TESMIN | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 89/379 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TGM4 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TMPRSS11B | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TP73 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 107/456 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRAPPC3L | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRBV28 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 75/459 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TRIM64 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPAN7 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC26 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 297/637 reads (47%) | called by muse, mutect2, varscan2
- TTC36 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 115/329 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.33185C>T p.P11062L (on ENST00000591111; = p.P10135L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/565 reads (23%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.19658C>T p.P6553L (on ENST00000591111; = p.P5626L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/442 reads (30%) | PolyPhen benign (0.288); called by muse, mutect2, varscan2
- UGT2B15 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- UNC93A | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- UPB1 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP17L10 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- XIRP2 | c.6697C>T p.Q2233* (on ENST00000628543; = p.Q2408* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 135/476 reads (28%) | called by muse, mutect2, varscan2
- ZBTB40 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZC4H2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZEB1 | c.2461A>T p.N821Y | Missense Mutation (SNP) | VAF 93/432 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF143 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ZNF16 | c.885T>G p.C295W | Missense Mutation (SNP) | VAF 74/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF17 | c.1325A>T p.Y442F | Missense Mutation (SNP) | VAF 114/385 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ZNF236 | c.4670C>T p.S1557F | Missense Mutation (SNP) | VAF 102/391 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ZNF292 | c.6550C>T p.Q2184* | Nonsense Mutation (SNP) | VAF 76/336 reads (23%) | called by muse, mutect2, varscan2
- ZNF439 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 124/441 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZNF546 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 132/479 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF621 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 105/458 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ZNF674 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM5 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 105/410 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ABCA9 | c.2832C>T p.A944= | Silent (SNP) | VAF 96/540 reads (18%) | called by muse, mutect2, varscan2
- ABCD4 | c.1236C>T p.S412= | Silent (SNP) | VAF 109/536 reads (20%) | catalogued as rs201164224; called by muse, mutect2, varscan2
- ABCD4 | c.621C>T p.P207= | Silent (SNP) | VAF 100/460 reads (22%) | called by muse, mutect2, varscan2
- ACSM2A | c.1668G>A p.G556= (on ENST00000219054; = p.G477= on NM_001308169.2) | Silent (SNP) | VAF 100/365 reads (27%) | catalogued as COSV54586355; called by muse, mutect2, varscan2
- ACTN4 | c.1668C>T p.I556= | Silent (SNP) | VAF 98/410 reads (24%) | catalogued as rs932227341, COSV99400773; called by muse, mutect2, varscan2
- ADAM18 | c.795C>T p.I265= | Silent (SNP) | VAF 194/516 reads (38%) | catalogued as COSV55843827; called by muse, mutect2, varscan2
- ADGRB3 | c.3654G>A p.R1218= | Silent (SNP) | VAF 95/393 reads (24%) | catalogued as rs928572184; called by muse, mutect2, varscan2
- AGAP4 | c.1317C>T p.S439= | Silent (SNP) | VAF 103/470 reads (22%) | called by muse, mutect2, varscan2
- AHNAK2 | c.690G>A p.T230= | Silent (SNP) | VAF 108/462 reads (23%) | catalogued as rs779805398, COSV60912200; called by muse, mutect2, varscan2
- ALPI | c.444C>T p.V148= | Silent (SNP) | VAF 84/376 reads (22%) | called by mutect2, varscan2
- ANKLE2 | c.2323T>C p.L775= | Silent (SNP) | VAF 107/477 reads (22%) | called by muse, mutect2, varscan2
- ANKRD7 | c.669G>A p.V223= | Silent (SNP) | VAF 245/534 reads (46%) | catalogued as rs766691129; called by muse, mutect2, varscan2
- ARFGEF2 | c.1938C>T p.I646= | Silent (SNP) | VAF 83/335 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.1800G>A p.Q600= | Silent (SNP) | VAF 120/472 reads (25%) | called by muse, mutect2, varscan2
- ARRB2 | c.177C>T p.T59= | Silent (SNP) | VAF 67/284 reads (24%) | called by muse, mutect2, varscan2
- ASXL2 | c.2655C>T p.S885= | Silent (SNP) | VAF 104/409 reads (25%) | catalogued as rs1209690038; called by muse, mutect2, varscan2
- ATP13A4 | c.2919C>T p.L973= | Silent (SNP) | VAF 101/439 reads (23%) | catalogued as COSV61315979; called by muse, mutect2, varscan2
- B4GALNT2 | c.276C>T p.F92= | Silent (SNP) | VAF 106/472 reads (22%) | catalogued as rs1176766580, COSV55925277, COSV55928319; called by muse, mutect2, varscan2
- BCL11A | c.900C>T p.G300= (on ENST00000335712 / NM_001365609.1; = p.G334= on NM_018014.4) | Silent (SNP) | VAF 131/455 reads (29%) | catalogued as rs752480226; called by muse, mutect2, varscan2
- BEX5 | c.18G>A p.K6= | Silent (SNP) | VAF 87/375 reads (23%) | called by muse, mutect2, varscan2
- BPIFB6 | c.834C>T p.I278= | Silent (SNP) | VAF 65/253 reads (26%) | called by muse, mutect2, varscan2
- C2 | c.537G>A p.S179= | Silent (SNP) | VAF 152/649 reads (23%) | catalogued as rs776980619, COSV54959959; called by muse, mutect2, varscan2
- C8orf34 | c.759C>T p.L253= | Silent (SNP) | VAF 65/226 reads (29%) | catalogued as rs749485435, COSV61377576; called by muse, mutect2, varscan2
- CACNA2D2 | c.1564C>T p.L522= | Silent (SNP) | VAF 108/405 reads (27%) | catalogued as COSV56569794; called by muse, mutect2, varscan2
- CASK | c.888G>A p.R296= | Silent (SNP) | VAF 86/354 reads (24%) | called by muse, mutect2, varscan2
- CATSPERG | c.264G>A p.P88= | Silent (SNP) | VAF 94/300 reads (31%) | catalogued as COSV53050776; called by muse, mutect2, varscan2
- CBLN2 | c.351C>T p.F117= | Silent (SNP) | VAF 53/200 reads (27%) | catalogued as COSV54050492, COSV54052288; called by muse, mutect2, varscan2
- CD1A | c.36C>T p.L12= | Silent (SNP) | VAF 227/364 reads (62%) | catalogued as rs1054190144, COSV56863678; called by muse, mutect2, varscan2
- CDC42BPG | c.4164C>T p.F1388= | Silent (SNP) | VAF 97/317 reads (31%) | catalogued as rs780390603, COSV61348318; called by muse, mutect2, varscan2
- CDH23 | c.6891G>A p.G2297= | Silent (SNP) | VAF 103/455 reads (23%) | called by muse, mutect2, varscan2
- CEACAM18 | c.897G>A p.E299= | Silent (SNP) | VAF 66/322 reads (20%) | called by muse, mutect2, varscan2
- CFAP54 | c.8559C>T p.F2853= | Silent (SNP) | VAF 77/324 reads (24%) | catalogued as COSV73047120; called by muse, mutect2, varscan2
- CNTN4 | c.2592C>T p.I864= | Silent (SNP) | VAF 96/397 reads (24%) | catalogued as COSV100639517; called by muse, mutect2, varscan2
- COL21A1 | c.24C>T p.L8= | Silent (SNP) | VAF 71/294 reads (24%) | catalogued as rs1226824346, COSV55163961; called by muse, mutect2, varscan2
- COL9A1 | c.1785G>A p.G595= | Silent (SNP) | VAF 92/339 reads (27%) | catalogued as rs753761775, COSV57895457; called by muse, mutect2, varscan2
- CRTC1 | c.555C>T p.V185= | Silent (SNP) | VAF 96/413 reads (23%) | catalogued as rs772569346, COSV58721653; called by muse, mutect2, varscan2
- CRTC3 | c.1491C>T p.F497= | Silent (SNP) | VAF 75/260 reads (29%) | catalogued as rs1157487113; called by muse, mutect2, varscan2
- CSGALNACT2 | c.33G>A p.R11= | Silent (SNP) | VAF 82/336 reads (24%) | catalogued as rs756124075; called by muse, mutect2, varscan2
- CSH2 | c.432G>A p.E144= | Silent (SNP) | VAF 203/572 reads (35%) | catalogued as COSV61080461; called by muse, mutect2, varscan2
- CUX1 | c.1140C>T p.P380= (on ENST00000292535 / NM_181552.4; = p.P391= on NM_001913.5) | Silent (SNP) | VAF 297/557 reads (53%) | catalogued as rs1554518003, COSV52904687; called by muse, mutect2, varscan2
- CXorf65 | c.66C>T p.V22= | Silent (SNP) | VAF 102/410 reads (25%) | catalogued as rs898952839, COSV52147792; called by muse, varscan2
- CYFIP1 | c.2532C>T p.F844= | Silent (SNP) | VAF 101/389 reads (26%) | called by muse, mutect2, varscan2
- CYP17A1 | c.1110C>T p.L370= | Silent (SNP) | VAF 69/336 reads (21%) | called by muse, mutect2, varscan2
- CYP2A13 | c.738C>T p.D246= | Silent (SNP) | VAF 124/553 reads (22%) | catalogued as rs373705937; called by muse, mutect2, varscan2
- DCC | c.513C>T p.I171= | Silent (SNP) | VAF 102/448 reads (23%) | catalogued as rs746357250; called by muse, mutect2, varscan2
- DCN | c.525G>A p.Q175= | Silent (SNP) | VAF 73/259 reads (28%) | called by muse, mutect2, varscan2
- DNAH6 | c.10428G>A p.K3476= | Silent (SNP) | VAF 121/384 reads (32%) | called by muse, mutect2, varscan2
- DNAH8 | c.3630C>T p.N1210= | Silent (SNP) | VAF 94/309 reads (30%) | catalogued as COSV100547540; called by muse, mutect2, varscan2
- DNM2 | c.1716C>T p.I572= (on ENST00000355667 / NM_001005360.3; = p.I568= on NM_004945.3) | Silent (SNP) | VAF 104/369 reads (28%) | catalogued as COSV58966731; called by muse, mutect2, varscan2
- DRD1 | c.120G>A p.G40= | Silent (SNP) | VAF 125/456 reads (27%) | catalogued as rs748030620, COSV67105280; called by muse, mutect2, varscan2
- EBF2 | c.765C>T p.I255= | Silent (SNP) | VAF 81/383 reads (21%) | catalogued as COSV68777803; called by muse, mutect2, varscan2
- EEFSEC | c.450C>T p.L150= | Silent (SNP) | VAF 94/431 reads (22%) | catalogued as COSV54626228; called by muse, mutect2, varscan2
- EFCAB3 | c.747G>A p.V249= | Silent (SNP) | VAF 130/619 reads (21%) | called by muse, mutect2, varscan2
- ENTPD3 | c.72C>T p.I24= | Silent (SNP) | VAF 99/363 reads (27%) | called by muse, mutect2, varscan2
- EPHA6 | c.3099C>T p.A1033= | Silent (SNP) | VAF 67/320 reads (21%) | called by muse, mutect2, varscan2
- ERG | c.1314G>A p.V438= (on ENST00000398919 / NM_001243428.1; = p.V414= on NM_004449.4) | Silent (SNP) | VAF 108/476 reads (23%) | called by muse, mutect2, varscan2
- EYS | c.210C>A p.G70= | Silent (SNP) | VAF 101/436 reads (23%) | called by muse, mutect2, varscan2
- F5 | c.6603C>T p.I2201= | Silent (SNP) | VAF 302/509 reads (59%) | catalogued as COSV63127661; called by muse, mutect2, varscan2
- FAM133A | c.426C>T p.S142= | Silent (SNP) | VAF 115/436 reads (26%) | called by muse, mutect2, varscan2
- FAM47C | c.1566C>T p.L522= | Silent (SNP) | VAF 157/650 reads (24%) | catalogued as COSV63726836; called by muse, mutect2, varscan2
- FREM2 | c.5505C>T p.A1835= | Silent (SNP) | VAF 120/473 reads (25%) | catalogued as COSV99751348; called by muse, mutect2, varscan2
- FSIP2 | c.19728G>A p.G6576= | Silent (SNP) | VAF 85/422 reads (20%) | called by muse, mutect2, varscan2
- GAD2 | c.993C>T p.L331= | Silent (SNP) | VAF 56/267 reads (21%) | catalogued as rs752124028, COSV52150370; called by muse, mutect2, varscan2
- GAL3ST1 | c.1260C>T p.F420= | Silent (SNP) | VAF 50/242 reads (21%) | catalogued as COSV58893455; called by muse, mutect2, varscan2
- GBP2 | c.549C>T p.F183= | Silent (SNP) | VAF 99/424 reads (23%) | called by muse, mutect2, varscan2
- GLT8D2 | c.684T>C p.P228= | Silent (SNP) | VAF 104/395 reads (26%) | called by muse, mutect2, varscan2
- GLYR1 | c.1368C>T p.T456= | Silent (SNP) | VAF 129/460 reads (28%) | called by muse, mutect2, varscan2
- GNPTAB | c.3576C>T p.F1192= | Silent (SNP) | VAF 63/305 reads (21%) | catalogued as COSV54777402; called by muse, mutect2, varscan2
- GNRHR | c.684G>A p.L228= | Silent (SNP) | VAF 84/369 reads (23%) | called by muse, mutect2, varscan2
- GOLGA6D | c.1614G>A p.P538= | Silent (SNP) | VAF 65/533 reads (12%) | catalogued as rs539641806; called by muse, mutect2, varscan2
- GOLGA6L1 | c.1536G>A p.R512= | Silent (SNP) | VAF 120/948 reads (13%) | catalogued as rs1419402962; called by muse, varscan2
- GPD1 | c.63C>T p.I21= | Silent (SNP) | VAF 75/308 reads (24%) | catalogued as rs772952491, COSV56547310; called by muse, mutect2, varscan2
- GPR157 | c.477C>T p.I159= | Silent (SNP) | VAF 79/341 reads (23%) | catalogued as rs772426416; called by muse, mutect2, varscan2
- GPR83 | c.943C>T p.L315= | Silent (SNP) | VAF 128/552 reads (23%) | catalogued as COSV54717629; called by muse, mutect2, varscan2
- GPRC6A | c.1815C>T p.I605= | Silent (SNP) | VAF 106/296 reads (36%) | catalogued as COSV59951894; called by muse, mutect2, varscan2
- GSG1L2 | c.498C>T p.F166= | Silent (SNP) | VAF 70/267 reads (26%) | called by muse, mutect2, varscan2
- GUCY2C | c.762C>T p.F254= | Silent (SNP) | VAF 74/301 reads (25%) | called by muse, mutect2, varscan2
- H1-3 | c.534G>A p.V178= | Silent (SNP) | VAF 112/430 reads (26%) | catalogued as rs746902474; called by mutect2, varscan2
- HDX | c.1992C>T p.F664= | Silent (SNP) | VAF 90/329 reads (27%) | called by muse, mutect2, varscan2
- HSPG2 | c.990C>T p.F330= | Silent (SNP) | VAF 98/403 reads (24%) | called by muse, mutect2, varscan2
- HTR3B | c.1164C>T p.I388= | Silent (SNP) | VAF 84/284 reads (30%) | called by muse, mutect2, varscan2
- HYDIN | c.4320C>T p.I1440= | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as COSV66831223, COSV66832841; called by muse, mutect2, varscan2
- IGFN1 | c.30C>T p.I10= | Silent (SNP) | VAF 201/329 reads (61%) | called by muse, mutect2, varscan2
- IL12B | c.828G>A p.Q276= | Silent (SNP) | VAF 91/307 reads (30%) | called by muse, mutect2, varscan2
- IRS4 | c.1605A>T p.S535= | Silent (SNP) | VAF 152/538 reads (28%) | called by muse, mutect2, varscan2
- ISG20 | c.465G>A p.A155= | Silent (SNP) | VAF 96/320 reads (30%) | catalogued as rs775056831; called by muse, mutect2, varscan2
- KCNB2 | c.1899C>T p.F633= | Silent (SNP) | VAF 114/593 reads (19%) | catalogued as rs1257842115, COSV73050382; called by muse, mutect2, varscan2
- KCNH6 | c.2550C>T p.L850= | Silent (SNP) | VAF 240/577 reads (42%) | called by muse, mutect2, varscan2
- KCNJ8 | c.27G>A p.P9= | Silent (SNP) | VAF 83/358 reads (23%) | called by muse, mutect2, varscan2
- KDM7A | c.801G>A p.Q267= | Silent (SNP) | VAF 99/650 reads (15%) | called by muse, mutect2, varscan2
- KIF14 | c.960C>T p.S320= | Silent (SNP) | VAF 284/519 reads (55%) | called by muse, mutect2, varscan2
- KIF18A | c.2295C>T p.D765= | Silent (SNP) | VAF 91/354 reads (26%) | called by muse, mutect2, varscan2
- KLHL3 | c.966C>T p.F322= | Silent (SNP) | VAF 61/341 reads (18%) | catalogued as rs750511635; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLRF2 | c.591G>A p.A197= | Silent (SNP) | VAF 78/317 reads (25%) | catalogued as rs956975056; called by muse, mutect2, varscan2
- KRTAP10-9 | c.744C>T p.S248= | Silent (SNP) | VAF 164/581 reads (28%) | catalogued as rs782090892; called by muse, mutect2, varscan2
- LACC1 | c.1141C>T p.L381= | Silent (SNP) | VAF 108/393 reads (27%) | catalogued as COSV57829310; called by muse, mutect2, varscan2
- LAMA1 | c.7867C>T p.L2623= | Silent (SNP) | VAF 107/400 reads (27%) | catalogued as rs527501893; ClinVar: likely benign; called by muse, mutect2, varscan2
- LARS1 | c.2586C>T p.F862= (on ENST00000394434 / NM_020117.11; = p.F835= on NM_016460.3) | Silent (SNP) | VAF 104/367 reads (28%) | catalogued as COSV50973674; called by muse, mutect2, varscan2
- LCN12 | c.132C>T p.F44= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as rs200874027, COSV65421642; called by muse, mutect2, varscan2
- LILRA6 | c.825G>A p.G275= | Silent (SNP) | VAF 181/1430 reads (13%) | called by muse, mutect2
- LINGO1 | c.1209G>A p.Q403= | Silent (SNP) | VAF 130/523 reads (25%) | catalogued as rs1297829471; called by muse, mutect2, varscan2
- LINGO2 | c.891C>T p.I297= | Silent (SNP) | VAF 121/331 reads (37%) | called by muse, mutect2, varscan2
- LRRC20 | c.549A>T p.L183= (on ENST00000355790 / NM_207119.3; = p.L127= on NM_018205.4) | Silent (SNP) | VAF 59/264 reads (22%) | called by muse, mutect2, varscan2
- LRRN1 | c.78C>T p.S26= | Silent (SNP) | VAF 74/331 reads (22%) | catalogued as COSV100076477; called by muse, mutect2, varscan2
- MAGEB17 | c.729G>A p.Q243= | Silent (SNP) | VAF 105/463 reads (23%) | called by muse, mutect2, varscan2
- MALRD1 | c.4062C>T p.I1354= | Silent (SNP) | VAF 103/334 reads (31%) | called by muse, mutect2, varscan2
- MAN2B2 | c.1851C>T p.F617= | Silent (SNP) | VAF 81/356 reads (23%) | catalogued as rs1017247266; called by muse, mutect2, varscan2
- MED15 | c.2247C>T p.L749= (on ENST00000263205 / NM_001003891.3; = p.L709= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/359 reads (28%) | catalogued as rs899740765; called by muse, mutect2, varscan2
- MEP1A | c.1590G>A p.S530= | Silent (SNP) | VAF 61/275 reads (22%) | catalogued as rs756665276, COSV57919116; called by muse, mutect2, varscan2
- MGLL | c.381C>T p.I127= (on ENST00000398104 / NM_001003794.2; = p.I137= on NM_007283.6) | Silent (SNP) | VAF 95/407 reads (23%) | catalogued as rs551038556; called by muse, mutect2, varscan2
- MROH5 | c.1866G>A p.L622= | Silent (SNP) | VAF 99/380 reads (26%) | called by muse, mutect2, varscan2
- MTM1 | c.1503G>A p.L501= | Silent (SNP) | VAF 49/218 reads (22%) | called by muse, mutect2, varscan2
- MUC19 | c.600C>T p.I200= | Silent (SNP) | VAF 78/321 reads (24%) | called by muse, mutect2, varscan2
- MUC22 | c.1698C>T p.T566= | Silent (SNP) | VAF 147/552 reads (27%) | called by muse, mutect2, varscan2
- MXRA5 | c.6345G>A p.K2115= | Silent (SNP) | VAF 174/590 reads (29%) | called by muse, mutect2, varscan2
- MYADML2 | c.705C>T p.T235= | Silent (SNP) | VAF 144/676 reads (21%) | called by muse, mutect2
- MYO18A | c.3186C>T p.S1062= | Silent (SNP) | VAF 86/389 reads (22%) | called by muse, mutect2, varscan2
- MYO6 | c.2620C>T p.L874= | Silent (SNP) | VAF 67/284 reads (24%) | called by muse, mutect2, varscan2
- NADK | c.534C>T p.I178= | Silent (SNP) | VAF 96/341 reads (28%) | catalogued as rs956974974; called by muse, mutect2, varscan2
- NALCN | c.1233C>T p.F411= | Silent (SNP) | VAF 73/288 reads (25%) | catalogued as COSV99213761; called by muse, mutect2, varscan2
- NCAN | c.345C>T p.S115= | Silent (SNP) | VAF 125/490 reads (26%) | called by muse, mutect2, varscan2
- NEB | c.13578G>A p.K4526= | Silent (SNP) | VAF 87/353 reads (25%) | called by muse, mutect2, varscan2
- NINL | c.174C>T p.F58= | Silent (SNP) | VAF 67/257 reads (26%) | catalogued as rs775693180, COSV54000535; called by muse, mutect2, varscan2
- NOM1 | c.1347C>T p.F449= | Silent (SNP) | VAF 220/447 reads (49%) | catalogued as rs775218645, COSV51981871; called by muse, mutect2, varscan2
- NPAP1 | c.2352C>T p.T784= | Silent (SNP) | VAF 107/435 reads (25%) | catalogued as rs1420335831, COSV61505105; called by muse, varscan2
- NPIPB11 | c.3465C>T p.P1155= | Silent (SNP) | VAF 89/425 reads (21%) | called by muse, mutect2, varscan2
- NPR1 | c.2118C>T p.L706= | Silent (SNP) | VAF 263/408 reads (64%) | called by muse, mutect2, varscan2
- NR1I2 | c.234C>T p.P78= | Silent (SNP) | VAF 115/490 reads (23%) | catalogued as COSV61977477, COSV61977531; called by muse, mutect2, varscan2
- NRXN3 | c.1875G>A p.Q625= (on ENST00000335750 / NM_001330195.2; = p.Q252= on NM_004796.6) | Silent (SNP) | VAF 112/518 reads (22%) | catalogued as rs781425884, COSV59721965; called by muse, mutect2, varscan2
- NTSR2 | c.798C>T p.I266= | Silent (SNP) | VAF 132/488 reads (27%) | catalogued as rs17853769, COSV60990864; called by muse, mutect2, varscan2
- NUCB1 | c.421C>T p.L141= | Silent (SNP) | VAF 69/240 reads (29%) | catalogued as COSV99618226; called by muse, mutect2, varscan2
- NUGGC | c.159G>A p.L53= | Silent (SNP) | VAF 100/266 reads (38%) | called by muse, mutect2, varscan2
- OOSP4A | c.297G>A p.T99= | Silent (SNP) | VAF 67/319 reads (21%) | catalogued as rs1326835635; called by muse, mutect2, varscan2
- OR1Q1 | c.711C>T p.T237= | Silent (SNP) | VAF 119/332 reads (36%) | called by muse, mutect2, varscan2
- OR2B3 | c.603C>T p.F201= | Silent (SNP) | VAF 131/598 reads (22%) | called by muse, mutect2, varscan2
- OR2H2 | c.705T>A p.A235= | Silent (SNP) | VAF 151/628 reads (24%) | called by muse, mutect2, varscan2
- OR2T3 | c.201C>T p.F67= | Silent (SNP) | VAF 208/485 reads (43%) | called by muse, mutect2, varscan2
- OR4D9 | c.435C>T p.I145= | Silent (SNP) | VAF 92/400 reads (23%) | catalogued as rs1440316852, COSV61434672; called by muse, mutect2, varscan2
- OR52N4 | c.965G>A p.*322= | Silent (SNP) | VAF 61/217 reads (28%) | called by muse, mutect2, varscan2
- OR6P1 | c.894G>A p.K298= | Silent (SNP) | VAF 320/525 reads (61%) | catalogued as COSV100583363; called by muse, mutect2, varscan2
- OR7D4 | c.139C>T p.L47= | Silent (SNP) | VAF 101/423 reads (24%) | catalogued as COSV58071069, COSV58071496, COSV58072540; called by muse, mutect2, varscan2
- OR8I2 | c.81T>A p.L27= | Silent (SNP) | VAF 88/347 reads (25%) | called by muse, mutect2, varscan2
- OR8I2 | c.888G>A p.V296= | Silent (SNP) | VAF 54/239 reads (23%) | called by muse, mutect2, varscan2
- OTOA | c.855C>T p.I285= | Silent (SNP) | VAF 77/326 reads (24%) | catalogued as COSV53750216; called by muse, mutect2, varscan2
- OTUD6A | c.318G>A p.R106= | Silent (SNP) | VAF 136/581 reads (23%) | catalogued as rs765977382; called by muse, mutect2, varscan2
- P2RY4 | c.609G>A p.A203= | Silent (SNP) | VAF 159/597 reads (27%) | catalogued as rs199814227; called by muse, mutect2, varscan2
- PABPC5 | c.373T>C p.L125= | Silent (SNP) | VAF 120/545 reads (22%) | called by muse, mutect2, varscan2
- PABPC5 | c.816G>A p.G272= | Silent (SNP) | VAF 158/575 reads (27%) | called by muse, mutect2, varscan2
- PCDH1 | c.3135C>T p.P1045= | Silent (SNP) | VAF 106/403 reads (26%) | called by muse, mutect2, varscan2
- PCDH15 | c.5008C>T p.L1670= (on ENST00000644397 / NM_001354429.2; = p.L1612= on NM_001142771.2) | Silent (SNP) | VAF 114/402 reads (28%) | catalogued as rs189102789, COSV64703056; called by muse, mutect2, varscan2
- PCDHAC2 | c.1896C>T p.L632= | Silent (SNP) | VAF 78/386 reads (20%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1377C>T p.F459= | Silent (SNP) | VAF 172/628 reads (27%) | catalogued as COSV50568585; called by muse, mutect2, varscan2
- PCDHGB3 | c.1263G>A p.T421= | Silent (SNP) | VAF 100/382 reads (26%) | catalogued as COSV53916783, COSV54032307; called by muse, mutect2, varscan2
- PCED1B | c.60C>T p.I20= | Silent (SNP) | VAF 90/352 reads (26%) | catalogued as rs781007128, COSV71395544; called by muse, mutect2, varscan2
- PCMTD2 | c.909C>T p.S303= | Silent (SNP) | VAF 147/527 reads (28%) | called by muse, mutect2, varscan2
- PCSK5 | c.2397G>A p.G799= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as COSV65088657; called by muse, mutect2, varscan2
- PGM2L1 | c.531C>T p.N177= | Silent (SNP) | VAF 66/289 reads (23%) | catalogued as rs971312524; called by muse, mutect2, varscan2
- PHYHIPL | c.1086G>A p.K362= | Silent (SNP) | VAF 88/331 reads (27%) | called by muse, mutect2, varscan2
- PIGK | c.159C>T p.S53= | Silent (SNP) | VAF 41/224 reads (18%) | called by muse, mutect2, varscan2
- PIK3C2A | c.288C>T p.T96= | Silent (SNP) | VAF 72/342 reads (21%) | catalogued as rs745732640; called by muse, mutect2, varscan2
- PLG | c.1722G>A p.P574= | Silent (SNP) | VAF 74/208 reads (36%) | catalogued as rs146030266; ClinVar: likely benign; called by muse, mutect2, varscan2
- PNLDC1 | c.918C>T p.F306= | Silent (SNP) | VAF 46/156 reads (29%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.898C>T p.L300= | Silent (SNP) | VAF 95/325 reads (29%) | called by muse, mutect2, varscan2
- POLR1B | c.2919C>T p.F973= | Silent (SNP) | VAF 123/448 reads (27%) | catalogued as COSV54496852; called by muse, mutect2, varscan2
- POLRMT | c.2724C>T p.S908= | Silent (SNP) | VAF 87/361 reads (24%) | catalogued as rs777344298; called by muse, mutect2, varscan2
- PPP1R12A | c.1965T>A p.T655= | Silent (SNP) | VAF 76/312 reads (24%) | catalogued as COSV54108388; called by muse, mutect2, varscan2
- PRAMEF18 | c.270C>A p.A90= | Silent (SNP) | VAF 70/696 reads (10%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.1251G>A p.E417= | Silent (SNP) | VAF 105/720 reads (15%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.240C>T p.F80= | Silent (SNP) | VAF 105/459 reads (23%) | called by muse, mutect2, varscan2
- PROM2 | c.1941G>A p.Q647= | Silent (SNP) | VAF 93/371 reads (25%) | catalogued as rs1447069107; called by muse, mutect2, varscan2
- PTPN6 | c.1374C>T p.G458= | Silent (SNP) | VAF 60/334 reads (18%) | called by muse, mutect2, varscan2
- PTPRD | c.4692C>T p.I1564= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as rs138863975; called by muse, mutect2, varscan2
- PUS10 | c.783C>T p.F261= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV100369482; called by muse, mutect2, varscan2
- RAB3IL1 | c.723C>T p.C241= | Silent (SNP) | VAF 101/381 reads (27%) | called by muse, mutect2, varscan2
- RASD2 | c.507C>T p.F169= | Silent (SNP) | VAF 117/466 reads (25%) | catalogued as rs773156408, COSV53352277; called by muse, mutect2, varscan2
- RASGRF2 | c.525C>T p.I175= | Silent (SNP) | VAF 69/320 reads (22%) | catalogued as rs763322899, COSV54133455, COSV54139948; called by muse, mutect2, varscan2
- RBCK1 | c.252C>T p.L84= (on ENST00000356286 / NM_031229.4; = p.L42= on NM_006462.6) | Silent (SNP) | VAF 78/294 reads (27%) | catalogued as COSV100675821, COSV100675983; called by muse, mutect2, varscan2
- RBMS3 | c.1026C>T p.H342= | Silent (SNP) | VAF 79/266 reads (30%) | called by muse, mutect2, varscan2
- REXO1 | c.2373C>T p.I791= | Silent (SNP) | VAF 77/325 reads (24%) | catalogued as rs192529831, COSV50096384; called by muse, mutect2, varscan2
- RGSL1 | c.282C>T p.F94= | Silent (SNP) | VAF 152/281 reads (54%) | catalogued as COSV54258699; called by muse, mutect2, varscan2
- SALL3 | c.1452C>T p.V484= | Silent (SNP) | VAF 148/668 reads (22%) | catalogued as COSV73306555; called by muse, mutect2, varscan2
- SCAPER | c.3915C>T p.F1305= | Silent (SNP) | VAF 97/394 reads (25%) | catalogued as COSV61306870; called by muse, mutect2, varscan2
- SCN10A | c.5379C>T p.V1793= | Silent (SNP) | VAF 127/450 reads (28%) | catalogued as rs367612792; called by muse, mutect2, varscan2
- SCUBE1 | c.1461G>A p.K487= | Silent (SNP) | VAF 95/376 reads (25%) | called by muse, mutect2, varscan2
- SDK2 | c.5668C>T p.L1890= | Silent (SNP) | VAF 128/556 reads (23%) | called by muse, mutect2, varscan2
- SELENOP | c.39C>T p.L13= | Silent (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- SEMA5B | c.2127G>A p.E709= | Silent (SNP) | VAF 95/355 reads (27%) | catalogued as rs770262806, COSV52101371, COSV52107275; called by muse, mutect2, varscan2
- SFPQ | c.1893T>C p.F631= | Silent (SNP) | VAF 60/266 reads (23%) | called by muse, mutect2, varscan2
- SFXN5 | c.816C>T p.S272= | Silent (SNP) | VAF 94/391 reads (24%) | catalogued as COSV99730103; called by muse, mutect2, varscan2
- SHROOM3 | c.1620C>T p.S540= | Silent (SNP) | VAF 111/412 reads (27%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.273C>T p.D91= | Silent (SNP) | VAF 118/467 reads (25%) | catalogued as COSV104390723; called by muse, mutect2, varscan2
- SIPA1L1 | c.2232G>A p.P744= | Silent (SNP) | VAF 170/391 reads (43%) | catalogued as rs200430873, COSV62168381; called by muse, mutect2, varscan2
- SLC22A13 | c.444C>T p.L148= | Silent (SNP) | VAF 97/376 reads (26%) | catalogued as rs775904889; called by muse, mutect2, varscan2
- SLC35G3 | c.519G>A p.V173= | Silent (SNP) | VAF 105/510 reads (21%) | catalogued as COSV99269156; called by muse, mutect2, varscan2
- SLC4A5 | c.2460C>T p.F820= | Silent (SNP) | VAF 70/318 reads (22%) | catalogued as rs267599453; called by muse, mutect2, varscan2
- SLC6A12 | c.309G>A p.G103= | Silent (SNP) | VAF 113/441 reads (26%) | called by muse, mutect2, varscan2
- SMAP1 | c.714C>T p.P238= (on ENST00000370455 / NM_001044305.3; = p.P211= on NM_021940.5) | Silent (SNP) | VAF 89/400 reads (22%) | called by muse, mutect2, varscan2
- SNTN | c.253C>T p.L85= | Silent (SNP) | VAF 65/327 reads (20%) | called by muse, mutect2, varscan2
- SNX29 | c.1515C>T p.L505= | Silent (SNP) | VAF 75/342 reads (22%) | catalogued as COSV60058082; called by muse, varscan2
- SPHKAP | c.1986C>T p.V662= | Silent (SNP) | VAF 92/369 reads (25%) | catalogued as rs61752224, COSV60872785; called by muse, mutect2, varscan2
- SPIC | c.483G>A p.R161= | Silent (SNP) | VAF 87/385 reads (23%) | called by muse, mutect2, varscan2
- SPTB | c.702G>A p.L234= | Silent (SNP) | VAF 95/356 reads (27%) | catalogued as rs1341623318; called by muse, mutect2, varscan2
- SRPX | c.1299G>A p.V433= | Silent (SNP) | VAF 111/480 reads (23%) | called by muse, varscan2
- ST14 | c.552G>A p.R184= | Silent (SNP) | VAF 98/295 reads (33%) | called by muse, mutect2, varscan2
- STRN3 | c.147G>A p.A49= | Silent (SNP) | VAF 149/539 reads (28%) | called by muse, mutect2, varscan2
- SYNDIG1L | c.10C>T p.L4= | Silent (SNP) | VAF 131/349 reads (38%) | called by muse, mutect2, varscan2
- SYT11 | c.1011C>T p.Y337= | Silent (SNP) | VAF 226/405 reads (56%) | called by muse, mutect2, varscan2
- TAL1 | c.642C>T p.I214= | Silent (SNP) | VAF 104/408 reads (25%) | catalogued as rs751120312; called by muse, mutect2, varscan2
- TANC2 | c.3553C>T p.L1185= | Silent (SNP) | VAF 140/329 reads (43%) | catalogued as rs370683714; called by muse, mutect2, varscan2
- TAS2R4 | c.207C>T p.F69= | Silent (SNP) | VAF 299/621 reads (48%) | catalogued as rs147698747; called by muse, mutect2, varscan2
- TENM4 | c.6714G>A p.R2238= | Silent (SNP) | VAF 120/419 reads (29%) | catalogued as COSV53630440; called by muse, mutect2, varscan2
- TENM4 | c.777G>A p.G259= | Silent (SNP) | VAF 79/397 reads (20%) | catalogued as rs1286102216; called by muse, mutect2, varscan2
- TERB1 | c.67C>T p.L23= | Silent (SNP) | VAF 69/225 reads (31%) | called by muse, mutect2, varscan2
- TESK1 | c.1305C>T p.C435= | Silent (SNP) | VAF 154/402 reads (38%) | called by muse, mutect2, varscan2
- TESPA1 | c.1362C>T p.S454= (on ENST00000316577 / NM_001098815.3; = p.S316= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 122/457 reads (27%) | called by muse, mutect2, varscan2
- TICRR | c.2859G>A p.K953= | Silent (SNP) | VAF 73/263 reads (28%) | catalogued as COSV51541360; called by muse, mutect2, varscan2
- TLN2 | c.1581G>A p.Q527= | Silent (SNP) | VAF 61/266 reads (23%) | called by muse, mutect2
- TM4SF18 | c.363C>T p.C121= | Silent (SNP) | VAF 113/452 reads (25%) | called by muse, mutect2, varscan2
- TMEM132A | c.597C>T p.S199= | Silent (SNP) | VAF 118/436 reads (27%) | catalogued as rs757144174; called by muse, mutect2, varscan2
- TMPRSS11B | c.115C>T p.L39= | Silent (SNP) | VAF 70/292 reads (24%) | catalogued as rs1257549025; called by muse, mutect2, varscan2
- TNRC6B | c.3702C>T p.S1234= (on ENST00000454349 / NM_001162501.2; = p.S1124= on NM_015088.3) | Silent (SNP) | VAF 58/274 reads (21%) | catalogued as COSV57304175; called by muse, mutect2, varscan2
- TP73 | c.1698G>A p.A566= | Silent (SNP) | VAF 109/456 reads (24%) | catalogued as rs772071972, COSV60700242; called by muse, mutect2, varscan2
- TPCN1 | c.624C>T p.F208= | Silent (SNP) | VAF 65/235 reads (28%) | called by muse, mutect2, varscan2
- TRAJ59 | c.18G>A p.R6= | Silent (SNP) | VAF 95/276 reads (34%) | catalogued as rs554761789; called by muse, mutect2, varscan2
- TRIM45 | c.669C>G p.P223= | Silent (SNP) | VAF 109/469 reads (23%) | catalogued as rs558692456; called by muse, mutect2, varscan2
- TRIM49B | c.472C>T p.L158= | Silent (SNP) | VAF 41/240 reads (17%) | catalogued as rs748251279, COSV60322815; called by muse, mutect2, varscan2
- TTN | c.100725G>A p.L33575= (on ENST00000591111; = p.L26151= on NM_003319.4) | Silent (SNP) | VAF 104/398 reads (26%) | called by muse, mutect2, varscan2
- TXNIP | c.880C>T p.L294= | Silent (SNP) | VAF 259/530 reads (49%) | catalogued as rs782154401; called by muse, mutect2, varscan2
- UBE2D2 | c.168C>T p.F56= | Silent (SNP) | VAF 85/353 reads (24%) | called by muse, mutect2, varscan2
- UCHL1 | c.108G>A p.E36= | Silent (SNP) | VAF 108/362 reads (30%) | called by muse, mutect2, varscan2
- UNC79 | c.4809G>A p.E1603= (on ENST00000393151 / NM_001346218.2; = p.E1426= on NM_020818.5) | Silent (SNP) | VAF 284/612 reads (46%) | called by muse, mutect2, varscan2
- URB1 | c.3120C>T p.L1040= | Silent (SNP) | VAF 105/434 reads (24%) | catalogued as rs539061617; called by muse, mutect2, varscan2
- VPS45 | c.1758G>A p.P586= (on ENST00000644526; = p.R555Q on NM_007259.5) | Silent (SNP) | VAF 282/551 reads (51%) | catalogued as rs142968690; called by muse, mutect2, varscan2
- VWA5A | c.2322C>T p.F774= | Silent (SNP) | VAF 83/248 reads (33%) | catalogued as rs779961083, COSV64414557; called by muse, mutect2, varscan2
- WDR20 | c.156C>T p.F52= | Silent (SNP) | VAF 93/449 reads (21%) | catalogued as rs549221821, COSV100085433; called by muse, mutect2, varscan2
- WIPI2 | c.408C>T p.S136= | Silent (SNP) | VAF 106/536 reads (20%) | called by muse, mutect2, varscan2
- XIRP1 | c.2565C>T p.L855= | Silent (SNP) | VAF 91/390 reads (23%) | called by muse, mutect2, varscan2
- ZBTB20 | c.36C>T p.N12= | Silent (SNP) | VAF 62/325 reads (19%) | called by muse, mutect2, varscan2
- ZBTB7A | c.798C>T p.A266= | Silent (SNP) | VAF 119/490 reads (24%) | called by muse, mutect2, varscan2
- ZER1 | c.1596G>A p.Q532= | Silent (SNP) | VAF 80/252 reads (32%) | called by muse, varscan2
- ZFC3H1 | c.5508C>T p.N1836= | Silent (SNP) | VAF 57/189 reads (30%) | called by muse, mutect2, varscan2
- ZNF236 | c.4671C>T p.S1557= | Silent (SNP) | VAF 100/392 reads (26%) | catalogued as rs1371937648; called by muse, mutect2, varscan2
- ZNF404 | c.54G>A p.E18= | Silent (SNP) | VAF 67/335 reads (20%) | catalogued as COSV60988405; called by muse, mutect2, varscan2
- ZNF43 | c.771C>T p.L257= | Silent (SNP) | VAF 90/370 reads (24%) | catalogued as COSV100731841; called by muse, mutect2, varscan2
- ZNF513 | c.786C>T p.P262= | Silent (SNP) | VAF 102/376 reads (27%) | catalogued as rs931444522; called by muse, mutect2, varscan2
- ZNF569 | c.390C>T p.F130= | Silent (SNP) | VAF 89/324 reads (27%) | catalogued as rs570264602; called by muse, mutect2, varscan2
- ZNF589 | c.330C>T p.F110= | Silent (SNP) | VAF 108/390 reads (28%) | called by muse, mutect2, varscan2
- ZNF594 | c.1068C>T p.T356= | Silent (SNP) | VAF 108/450 reads (24%) | called by muse, mutect2, varscan2
- ZNF865 | c.375C>T p.P125= | Silent (SNP) | VAF 128/526 reads (24%) | catalogued as rs554751365; called by muse, varscan2
- AC092718.9 | chr16:81154111 C>T | 3'Flank (SNP) | VAF 87/278 reads (31%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58839658 G>A | 5'Flank (SNP) | VAF 106/453 reads (23%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840365 G>A | 5'Flank (SNP) | VAF 106/465 reads (23%) | catalogued as rs942246524; called by muse, mutect2, varscan2
- ANXA8 | c.207+18G>T | Intron (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.989-13C>T | Intron (SNP) | VAF 126/473 reads (27%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+274C>T | Intron (SNP) | VAF 147/610 reads (24%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27571857 G>A | 5'Flank (SNP) | VAF 108/357 reads (30%) | catalogued as rs552443384; called by muse, mutect2, varscan2
- CNOT3 | c.2037+42C>T | Intron (SNP) | VAF 146/490 reads (30%) | catalogued as rs373905326; called by muse, mutect2, varscan2
23 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 23 other) are not listed here.
